Somatic mutation profile of cancer-model specimen HCM-CSHL-0239-C18-85A (3D Organoid; aliquot HCM-CSHL-0239-C18-85A-01D-A78J-36), derived from the primary tumor of HCMI case HCM-CSHL-0239-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.0 years (20,072 days).
Specimen HCM-CSHL-0239-C18-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 2440f90a-e0c0-4087-9207-9c1e3c4a51bf.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0239-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0239-C18-10A-01D-A78J-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9ef24b68-ed25-42b3-88d5-6f9f31bc5684

The open-access MAF lists 145 somatic variants for this specimen: 93 protein-altering or splice-affecting, 35 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 35, 3'UTR 6, Nonsense Mutation 6, Intron 6, Frame Shift Ins 5, Frame Shift Del 5, Splice Region 3, RNA 3, Splice Site 1, 5'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.707A>G p.Y236C | Missense Mutation (SNP) | VAF 181/202 reads (90%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs730882026, CM004907, COSV52662150, COSV52735723, COSV53167431; ClinVar: likely pathogenic; called by muse, varscan2
- ABCC8 | c.602C>T p.P201L | Missense Mutation (SNP) | VAF 65/254 reads (26%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.573); catalogued as rs933815442; called by muse, mutect2, varscan2
- ADGRL3 | c.2816C>T p.A939V (on ENST00000506720 / NM_001322402.2; = p.A871V on NM_015236.6) | Missense Mutation (SNP) | VAF 58/194 reads (30%) | SIFT tolerated (0.34); PolyPhen benign (0.066); catalogued as rs777017067, COSV101546801, COSV72230433; called by muse, mutect2, varscan2
- ALCAM | c.914G>A p.R305H | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1262196322; called by muse, mutect2, varscan2
- APC | c.3942del p.R1314Sfs*7 | Frame Shift Del (DEL) | VAF 169/258 reads (66%) | catalogued as COSV57371145; called by mutect2, pindel, varscan2
- ARHGAP31 | c.348G>A p.T116= | Splice Region (SNP) | VAF 52/155 reads (34%) | catalogued as rs749601853, COSV99956942; called by muse, mutect2, varscan2
- ARHGEF4 | c.712G>A p.D238N | Missense Mutation (SNP) | VAF 33/127 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs759872047, COSV58123575, COSV58129852; called by muse, mutect2, varscan2
- BRINP2 | c.506G>T p.R169I | Missense Mutation (SNP) | VAF 66/166 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.403); catalogued as COSV64175026, COSV64181319; called by muse, mutect2, varscan2
- BTNL3 | c.847G>A p.A283T | Missense Mutation (SNP) | VAF 25/233 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); catalogued as rs201534771, COSV61565707, COSV61566065; called by muse, mutect2, varscan2
- CDH2 | c.2462C>T p.P821L | Missense Mutation (SNP) | VAF 177/190 reads (93%) | SIFT tolerated (0.15); PolyPhen probably damaging (1); catalogued as rs768097198; called by muse, mutect2, varscan2
- CES1 | c.955C>A p.L319M | Missense Mutation (SNP) | VAF 70/297 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.193); catalogued as COSV100828742; called by muse, mutect2, varscan2
- CFAP46 | c.7930G>A p.G2644S | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs1342524342; called by muse, mutect2, varscan2
- COQ10B | c.185G>A p.R62Q | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.756); catalogued as rs776608625, COSV55836205; called by muse, mutect2, varscan2
- DYNC1I1 | c.1049G>A p.R350H | Missense Mutation (SNP) | VAF 36/119 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.714); catalogued as rs376275541, COSV61461083; called by muse, varscan2
- EPB41L1 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 570/1654 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as rs779328780, COSV52438381; called by muse, mutect2, varscan2
- EVC2 | c.2929C>T p.R977W | Missense Mutation (SNP) | VAF 133/460 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as rs140316127; called by muse, mutect2, varscan2
- FBXL7 | c.1427G>A p.R476H | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.05); PolyPhen benign (0.075); catalogued as rs1341792515, COSV61645247; called by muse, varscan2
- FH | c.310G>A p.A104T | Missense Mutation (SNP) | VAF 83/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1303488878, COSV100844968; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- HAPLN4 | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 157/299 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs961855111; called by muse, mutect2, varscan2
- HEG1 | c.2645C>A p.S882* | Nonsense Mutation (SNP) | VAF 23/281 reads (8%) | catalogued as rs752436571; called by muse, mutect2
- HNRNPCL2 | c.610dup p.I204Nfs*2 | Frame Shift Ins (INS) | VAF 85/295 reads (29%) | catalogued as rs766966451; called by mutect2, pindel, varscan2
- IFNA1 | c.442C>T p.R148* | Nonsense Mutation (SNP) | VAF 35/172 reads (20%) | catalogued as rs777221783, COSV52806429; called by muse, mutect2, varscan2
- KHDC1 | c.233C>T p.T78M (on ENST00000370384 / NM_001251874.2; = p.T5M on NM_030568.5) | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT tolerated (0.19); PolyPhen benign (0.011); catalogued as rs774462256, COSV100001740; called by muse, mutect2, varscan2
- KIF2B | c.799G>A p.D267N | Missense Mutation (SNP) | VAF 165/226 reads (73%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1260059640, COSV52129098; called by muse, mutect2, varscan2
- MCM3AP | c.4819G>A p.A1607T | Missense Mutation (SNP) | VAF 169/176 reads (96%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as rs190933622, COSV52439372; called by muse, mutect2, varscan2
- MEOX2 | c.219C>A p.H73Q | Missense Mutation (SNP) | VAF 59/233 reads (25%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as COSV100012552; called by muse, varscan2
- NFATC1 | c.1459C>T p.R487C | Missense Mutation (SNP) | VAF 79/214 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.465); catalogued as rs758037357, COSV53701290; called by muse, mutect2, varscan2
- PCDHA12 | c.2159C>T p.A720V | Missense Mutation (SNP) | VAF 111/257 reads (43%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.021); catalogued as COSV56497066; called by muse, mutect2, varscan2
- POM121L12 | c.787G>A p.A263T | Missense Mutation (SNP) | VAF 163/280 reads (58%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.045); catalogued as rs749141757, COSV68692580, COSV68693810; called by muse, mutect2, varscan2
- RELN | c.5360G>A p.R1787Q | Missense Mutation (SNP) | VAF 117/465 reads (25%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.963); catalogued as rs372887562; called by muse, mutect2, varscan2
- RFX6 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 116/332 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.666); catalogued as rs1353404589, COSV60587723; called by muse, mutect2, varscan2
- RIMS2 | c.1522C>T p.R508C (on ENST00000666250 / NM_001348490.2; = p.R316C on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 165/638 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376615886; called by muse, mutect2, varscan2
- RSPO1 | c.92G>A p.R31Q | Missense Mutation (SNP) | VAF 108/247 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as rs749070990, COSV62974774; called by muse, mutect2, varscan2
- SMARCA2 | c.4750G>C p.G1584R | Missense Mutation (SNP) | VAF 98/185 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.02); catalogued as rs887291939; called by muse, mutect2, varscan2
- SPANXN3 | c.71dup p.N24Kfs*2 | Frame Shift Ins (INS) | VAF 52/63 reads (83%) | catalogued as rs781940283; called by mutect2, varscan2
- SSTR3 | c.740G>A p.R247Q | Missense Mutation (SNP) | VAF 76/218 reads (35%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as rs766144463; called by muse, mutect2, varscan2
- TMF1 | c.1849G>A p.V617I | Missense Mutation (SNP) | VAF 24/43 reads (56%) | SIFT tolerated (0.18); PolyPhen benign (0.005); catalogued as rs763915078; called by muse, mutect2, varscan2
- TRIM48 | c.383G>C p.C128S | Missense Mutation (SNP) | VAF 105/449 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101338238; called by muse, mutect2, varscan2
- TRPS1 | c.1643G>A p.R548H (on ENST00000220888 / NM_001330599.2; = p.R561H on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/409 reads (10%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.866); catalogued as rs371005211; called by muse, mutect2, varscan2
- TTLL4 | c.1513C>G p.Q505E | Missense Mutation (SNP) | VAF 37/174 reads (21%) | SIFT tolerated (0.21); PolyPhen benign (0.018); catalogued as rs758954798, COSV51436788; called by muse, mutect2, varscan2
- XKR6 | c.1573G>A p.D525N | Missense Mutation (SNP) | VAF 37/43 reads (86%) | SIFT tolerated (0.22); PolyPhen benign (0.223); catalogued as rs748823161; called by muse, mutect2, varscan2
- ZNF98 | c.305dup p.N102Kfs*12 | Frame Shift Ins (INS) | VAF 9/21 reads (43%) | catalogued as rs757764317; called by mutect2, varscan2
- ADGRV1 | c.14518G>C p.V4840L | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.444); called by muse, mutect2
- AHNAK2 | c.11462C>A p.S3821Y | Missense Mutation (SNP) | VAF 11/296 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.605); called by muse, mutect2
- BLOC1S3 | c.382G>C p.V128L | Missense Mutation (SNP) | VAF 7/130 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.003); called by muse, mutect2
- C4orf17 | c.419A>G p.K140R | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CBFA2T2 | c.770C>A p.A257D | Missense Mutation (SNP) | VAF 84/892 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.422); called by muse, mutect2
- CEP250 | c.1956G>C p.K652N | Missense Mutation (SNP) | VAF 139/1576 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2
- CLEC2B | c.356G>T p.G119V | Missense Mutation (SNP) | VAF 84/306 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CNTN6 | c.419_428del p.V140Afs*56 | Frame Shift Del (DEL) | VAF 14/54 reads (26%) | called by mutect2, pindel, varscan2
- CPA1 | c.649C>G p.L217V | Missense Mutation (SNP) | VAF 77/214 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- CSMD3 | c.8470G>C p.V2824L (on ENST00000297405 / NM_001363185.1; = p.V2655L on NM_052900.3) | Missense Mutation (SNP) | VAF 113/492 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- CYP51A1 | c.1249C>G p.L417V | Missense Mutation (SNP) | VAF 55/203 reads (27%) | SIFT tolerated (0.19); PolyPhen benign (0.22); called by muse, mutect2, varscan2
- DOCK10 | c.2322A>T p.K774N | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- DOCK10 | c.2320A>T p.K774* | Nonsense Mutation (SNP) | VAF 14/128 reads (11%) | called by muse, mutect2
- DSP | c.7972G>A p.G2658S | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLT8D2 | c.991T>A p.W331R | Missense Mutation (SNP) | VAF 89/153 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HOXB6 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 33/130 reads (25%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KALRN | c.8714G>A p.C2905Y (on ENST00000360013 / NM_001024660.4; = p.C1208Y on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 75/329 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.138); called by muse, mutect2, varscan2
- KCNH7 | c.605C>G p.S202C | Missense Mutation (SNP) | VAF 79/376 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- KCTD3 | c.2327C>G p.S776* | Nonsense Mutation (SNP) | VAF 72/126 reads (57%) | called by muse, mutect2, varscan2
- KPNA3 | c.1444G>T p.D482Y | Missense Mutation (SNP) | VAF 30/135 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- LPIN1 | c.2295-3C>A | Splice Region (SNP) | VAF 15/171 reads (9%) | called by muse, mutect2
- MBTPS1 | c.3060A>C p.Q1020H | Missense Mutation (SNP) | VAF 52/165 reads (32%) | SIFT tolerated, low confidence (0.28); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- NAV2 | c.6812dup p.H2271Qfs*2 (on ENST00000396087 / NM_001244963.2; = p.H2212Qfs*2 on NM_145117.5) | Frame Shift Ins (INS) | VAF 34/253 reads (13%) | called by pindel, varscan2
- NBEAL1 | c.591_594del p.F198Ifs*26 | Frame Shift Del (DEL) | VAF 10/76 reads (13%) | called by pindel, varscan2
- NCOA6 | c.4127T>G p.V1376G | Missense Mutation (SNP) | VAF 66/770 reads (9%) | SIFT tolerated (0.51); PolyPhen benign (0.086); called by muse, mutect2
- NETO2 | c.961A>T p.N321Y | Missense Mutation (SNP) | VAF 51/223 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NFIC | c.887G>C p.G296A | Missense Mutation (SNP) | VAF 119/211 reads (56%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- NKRF | c.1369G>T p.D457Y | Missense Mutation (SNP) | VAF 47/105 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); called by muse, mutect2, varscan2
- PADI3 | c.161C>G p.P54R | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- PDZD2 | c.4956del p.L1652Ffs*20 | Frame Shift Del (DEL) | VAF 86/219 reads (39%) | called by mutect2, pindel, varscan2
- PGBD2 | c.980G>C p.G327A | Missense Mutation (SNP) | VAF 77/246 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- PITRM1 | c.1119C>A p.D373E | Missense Mutation (SNP) | VAF 53/161 reads (33%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- PLK4 | c.1009T>A p.S337T | Missense Mutation (SNP) | VAF 53/93 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- POLR3A | c.2486C>A p.A829D | Missense Mutation (SNP) | VAF 132/507 reads (26%) | SIFT tolerated (0.55); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- PREX1 | c.1072G>C p.G358R | Missense Mutation (SNP) | VAF 74/970 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- PRKG2 | c.686C>T p.T229I | Missense Mutation (SNP) | VAF 36/70 reads (51%) | SIFT deleterious (0.03); PolyPhen benign (0.345); called by muse, mutect2, varscan2
- R3HDML | c.585C>A p.N195K | Missense Mutation (SNP) | VAF 52/610 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.059); called by muse, mutect2
- RASSF6 | c.449C>G p.P150R (on ENST00000342081 / NM_201431.2; = p.P118R on NM_177532.5) | Missense Mutation (SNP) | VAF 104/168 reads (62%) | SIFT deleterious (0.01); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- RFC4 | c.779_780del p.K260Sfs*12 | Frame Shift Del (DEL) | VAF 39/181 reads (22%) | called by mutect2, pindel, varscan2
- SBF2 | c.1886A>C p.N629T | Missense Mutation (SNP) | VAF 13/452 reads (3%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2
- SLCO1A2 | c.1204T>A p.Y402N | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated (0.31); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SYCP2 | c.2772A>G p.K924= | Splice Region (SNP) | VAF 20/157 reads (13%) | called by muse, mutect2, varscan2
- TMEM176A | c.83C>A p.A28D | Missense Mutation (SNP) | VAF 57/238 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- UNC80 | c.2749C>A p.H917N | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- YPEL1 | c.17dup p.S7Vfs*28 | Frame Shift Ins (INS) | VAF 60/244 reads (25%) | called by mutect2, pindel, varscan2
- ZAN | c.8414-2A>C p.X2805_splice | Splice Site (SNP) | VAF 70/247 reads (28%) | called by muse, mutect2, varscan2
- ZFHX2 | c.3493G>A p.A1165T | Missense Mutation (SNP) | VAF 45/161 reads (28%) | SIFT tolerated (0.08); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- ZFHX4 | c.8896A>G p.I2966V | Missense Mutation (SNP) | VAF 17/129 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); called by muse, mutect2, varscan2
- ZNF157 | c.940A>T p.K314* | Nonsense Mutation (SNP) | VAF 52/110 reads (47%) | called by muse, mutect2, varscan2
- ZNF804A | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 33/121 reads (27%) | called by muse, mutect2, varscan2
- ZNF850 | c.2671C>T p.H891Y | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- AHNAK2 | c.11244G>A p.L3748= | Silent (SNP) | VAF 319/326 reads (98%) | called by muse, mutect2, varscan2
- AJM1 | c.414G>A p.A138= | Silent (SNP) | VAF 43/63 reads (68%) | catalogued as rs1227562744; called by muse, varscan2
- BOD1L1 | c.684G>A p.K228= | Silent (SNP) | VAF 116/435 reads (27%) | called by muse, mutect2, varscan2
- CCDC92 | c.864C>T p.H288= | Silent (SNP) | VAF 35/110 reads (32%) | catalogued as rs750311604; called by muse, mutect2, varscan2
- CELA3A | c.348G>T p.S116= | Silent (SNP) | VAF 41/80 reads (51%) | called by muse, mutect2, varscan2
- CNTN2 | c.2295C>T p.G765= | Silent (SNP) | VAF 12/395 reads (3%) | catalogued as COSV59353462; called by muse, mutect2
- CRB1 | c.549C>T p.C183= | Silent (SNP) | VAF 94/166 reads (57%) | catalogued as rs756544059; called by muse, mutect2, varscan2
- CRB2 | c.576G>A p.P192= | Silent (SNP) | VAF 48/147 reads (33%) | catalogued as rs1040869162; called by muse, mutect2, varscan2
- DDR2 | c.666A>C p.G222= | Silent (SNP) | VAF 66/199 reads (33%) | called by muse, mutect2, varscan2
- DIP2B | c.249T>C p.S83= | Silent (SNP) | VAF 72/229 reads (31%) | catalogued as rs745727513; called by muse, mutect2, varscan2
- DPYS | c.303C>T p.F101= | Silent (SNP) | VAF 84/898 reads (9%) | catalogued as rs141057778; called by muse, mutect2
- EBAG9 | c.69G>A p.K23= | Silent (SNP) | VAF 53/582 reads (9%) | catalogued as COSV61753283; called by muse, mutect2
- EIPR1 | c.612G>A p.A204= | Silent (SNP) | VAF 176/383 reads (46%) | catalogued as rs754801494; called by muse, mutect2, varscan2
- EPHB6 | c.309G>A p.A103= | Silent (SNP) | VAF 241/422 reads (57%) | catalogued as rs370537878; called by muse, mutect2, varscan2
- FAT4 | c.13755C>A p.I4585= | Silent (SNP) | VAF 72/255 reads (28%) | catalogued as COSV100629211, COSV58691432; called by muse, mutect2, varscan2
- FLACC1 | c.591G>A p.K197= | Silent (SNP) | VAF 18/313 reads (6%) | called by muse, mutect2
- FUT7 | c.57C>T p.A19= | Silent (SNP) | VAF 303/534 reads (57%) | catalogued as rs757216024; called by muse, mutect2, varscan2
- GPAT2 | c.1905C>T p.G635= | Silent (SNP) | VAF 96/178 reads (54%) | catalogued as COSV100853219; called by muse, mutect2, varscan2
- HES3 | c.213C>T p.S71= | Silent (SNP) | VAF 80/193 reads (41%) | catalogued as rs750211535; called by muse, mutect2, varscan2
- HOXD1 | c.18G>A p.E6= | Silent (SNP) | VAF 111/425 reads (26%) | catalogued as rs756995034; called by muse, mutect2, varscan2
- IFIT3 | c.96G>A p.R32= | Silent (SNP) | VAF 25/114 reads (22%) | called by muse, mutect2, varscan2
- KANSL2 | c.351C>T p.C117= | Silent (SNP) | VAF 44/207 reads (21%) | called by muse, mutect2, varscan2
- KLRF1 | c.117C>A p.I39= | Silent (SNP) | VAF 37/133 reads (28%) | catalogued as COSV54380299; called by muse, mutect2, varscan2
- LRP1 | c.5157C>T p.T1719= | Silent (SNP) | VAF 20/290 reads (7%) | catalogued as rs752348684, COSV54513421; called by muse, mutect2
- MSI1 | c.276T>G p.P92= | Silent (SNP) | VAF 23/67 reads (34%) | called by muse, mutect2, varscan2
- NAV3 | c.3591A>G p.T1197= | Silent (SNP) | VAF 87/286 reads (30%) | catalogued as rs1167459934; called by muse, mutect2, varscan2
- NKX1-1 | c.552G>A p.A184= | Silent (SNP) | VAF 16/366 reads (4%) | called by muse, mutect2
- NRP2 | c.1845C>T p.T615= | Silent (SNP) | VAF 107/366 reads (29%) | catalogued as rs867179644; called by muse, mutect2, varscan2
- PAX3 | c.141C>T p.N47= | Silent (SNP) | VAF 120/522 reads (23%) | catalogued as CM961088; called by muse, mutect2
- RANBP17 | c.1887T>G p.L629= | Silent (SNP) | VAF 36/45 reads (80%) | called by muse, mutect2, varscan2
- RTBDN | c.654C>A p.G218= (on ENST00000393233 / NM_001270444.1; = p.G250= on NM_031429.2) | Silent (SNP) | VAF 10/292 reads (3%) | called by muse, mutect2
- TENM4 | c.1779C>T p.G593= | Silent (SNP) | VAF 34/159 reads (21%) | catalogued as rs1355154660; called by muse, mutect2, varscan2
- THBD | c.1503C>T p.P501= | Silent (SNP) | VAF 86/535 reads (16%) | catalogued as rs373402912; called by muse, mutect2, varscan2
- TMEM129 | c.390C>G p.L130= | Silent (SNP) | VAF 30/95 reads (32%) | called by muse, mutect2
- TTN | c.3318C>T p.G1106= (on ENST00000591111; = p.G1060= on NM_003319.4) | Silent (SNP) | VAF 241/477 reads (51%) | catalogued as rs141768043; ClinVar: uncertain significance / likely benign / benign; called by muse, mutect2, varscan2
- AC104078.1 | n.315G>C | RNA (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- ADGRB2 | c.*49T>C | 3'UTR (SNP) | VAF 18/61 reads (30%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2287G>A | 3'UTR (SNP) | VAF 65/133 reads (49%) | catalogued as rs1171932777; called by muse, mutect2, varscan2
- DNM1P46 | chr15:99808200 G>C | 5'Flank (SNP) | VAF 8/192 reads (4%) | called by muse, mutect2
- FAM120B | c.*2C>T | 3'UTR (SNP) | VAF 23/183 reads (13%) | called by muse, mutect2, varscan2
- FER1L4 | n.3633T>C | RNA (SNP) | VAF 90/1150 reads (8%) | catalogued as rs1336885603; called by muse, mutect2
- JAKMIP3 | c.*292G>A | 3'UTR (SNP) | VAF 102/170 reads (60%) | catalogued as rs114837050; called by muse, mutect2, varscan2
- LHX1 | c.675+14G>A | Intron (SNP) | VAF 28/166 reads (17%) | catalogued as rs1186726122; called by muse, mutect2, varscan2
- MUC15 | c.*18C>T | 3'UTR (SNP) | VAF 42/171 reads (25%) | catalogued as rs767780292, COSV55552880; called by muse, mutect2, varscan2
- NR1D2 | c.1146+623G>T | Intron (SNP) | VAF 49/143 reads (34%) | called by muse, mutect2, varscan2
- PTN | c.-201G>T | 5'UTR (SNP) | VAF 50/162 reads (31%) | called by muse, mutect2, varscan2
- SGIP1 | c.*39G>A | 3'UTR (SNP) | VAF 18/55 reads (33%) | catalogued as rs765036166; called by mutect2, varscan2
- SLC66A1L | n.558A>G | RNA (SNP) | VAF 57/199 reads (29%) | catalogued as COSV101456719; called by muse, mutect2, varscan2
- TMEM116 | c.-199+1481G>T | Intron (SNP) | VAF 32/94 reads (34%) | called by muse, mutect2, varscan2
- TMEM199 | c.376-10_376-9insG | Intron (INS) | VAF 32/195 reads (16%) | called by mutect2, pindel, varscan2
- USH1C | c.1284+7677G>A | Intron (SNP) | VAF 42/176 reads (24%) | called by muse, mutect2, varscan2
- ZMAT4 | c.103-19039T>G | Intron (SNP) | VAF 35/167 reads (21%) | called by muse, mutect2, varscan2
